Surgical pathology report (de-identified scan), TCGA case TCGA-24-1463, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1463-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient

Address:

Gender: F

DOB:

Physician(s):

Service:

Location:

MRN:

Hospital #

Patient Type:

Accession

Taken

Received:

Reported:

Other Related Clinical Data:

DIAGNOSIS: OMENTUM, EXCISION

- POORLY DIFFERENTIATED ADENOCARCINOMA (SEE COMMENT)

OMENTUM, #3, EXCISION

- POORLY DIFFERENTIATED ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- MICROSCOPIC FOCI OF MODERATELY DIFFERENTIATED ADENOCARCINOMA (SEE COMMENT)

- LOWER UTERINE SEGMENT IS FREE OF CARCINOMA

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- LEIOMYOMAS, LARGEST 1.5 CM

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA

OVARY, ONE SIDE, SALPINGO OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING SURFACE ADHESIONS

FALLOPIAN TUBE, SIDE ONE, SALPINGO OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING FALLOPIAN TUBE LUMEN

OVARY, SIDE TWO, SALPINGO OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING SURFACE ADHESIONS

[page 2 of 3]
Patient Name:

DOB:

- FALLOPIAN TUBE, SIDE TWO, SALPINGO OOPHORECTOMY
- POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING PERITUBAL SOFT TISSUE
- TUBO-OVARIAN ADHESIONS

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

**

Intraoperative Consultation: An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick up "omentum," consisting of a 13.8 x 6.5 x 4.9 cm omental cake nearly entirely replaced by metastatic tan-grey tumor. A portion is frozen for FS and a portion of tumor retained for Tumor Repository," by

FS1: Omentum, omentectomy - "Poorly differentiated carcinoma, consistent with Mullerian origin," by

Microscopic Description and Comment: Poorly differentiated adenocarcinoma of mixed epithelial type, with endometrioid and serous differentiation, is present in multiple locations. The bulk of the tumor is in the omentum which is diffusely replaced, but large tumor implants are also present on the uterine serosa and on the surfaces only of both ovaries. One fallopian tube is distended by a 1.5 cm nodule of tumor in the lumen. Poorly differentiated adenocarcinoma is present in the peritubal soft tissue of the other fallopian tube. Because of the history of endometrial adenocarcinoma in a recent endometrial biopsy performed at an outside institution, the entire endometrium has been submitted for histologic evaluation. Very focal microscopic foci of moderately differentiated adenocarcinoma of endometrioid type are present. There is no associated myometrial or lymphovascular space invasion. Sections of lower uterine segment and cervix are free of carcinoma. Several small leiomyomas are identified within myometrium, the largest measuring 1.5 cm.

When tumor is present in multiple locations in the female genital tract it is difficult to determine whether tumor in one location is metastatic from another site or whether they represent synchronous primary tumors. Because the bulk of the tumor in this case is peritoneal, and the tumor in the endometrium is microscopic and not associated with myometrial or lymphovascular space invasion, I favor that these represent synchronous primary peritoneal and endometrial carcinomas or that the endometrial carcinoma is metastatic from the peritoneum.

History: The patient is a year old woman with omental cake, abnormal ovaries and carcinoma of the endometrium (biopsied at - poorly differentiated adenocarcinoma). Operative procedure: Laparotomy; omentectomy; total abdominal hysterectomy and bilateral salpingo-oophorectomy; radical tumor debulking.

Specimen(s) Received:

- A: OMENTUM, ROUTINE
- B: OMENTUM, ROUTINE
- C: UTERUS, CERVIX, BSO

Gross Description The specimens are received in three formalin-filled containers labeled with the patient's name. The first container is labeled "omentum, FS." It consists of a portion of omental fat measuring 18 x 17 x 4 cm occupied by multiple nodules of solid tan, friable focal papillary tumor. The tumor occupies the entire portion of omentum submitted.

[page 3 of 3]
Patient Name:

DOB:

In addition, the container holds a cassette labeled "FS." Labeled A1 - FS; A2, and A3 - additional sections of tumor. Jar 3.

The second container is labeled "omentum #3." It holds multiple irregular fragments of omental fat occupied by multiple tumor nodules, ranging in size from 0.5 to 3 cm. The specimen measures 10 x 10 x 4 cm in aggregate. Sections of tumor nodules labeled B1. Jar 2.

The third container is labeled "uterus, cervix, BSO." It holds a uterus including cervix and two detached ovaries with corresponding fallopian tube. The uterus is 50 grams and 6 x 3.5 x 3 cm. The uterine serosa on one aspect, which appears to be the anterior aspect, shows a 3 x 2 cm solid and papillary tan tumor implant. The remaining uterine serosa is smooth. The ectocervical mucosa is white, shiny and flat. The cervix is 2.5 cm in diameter. The endocervical canal measures 2.5 cm in length and is lined by yellow, flat unremarkable endocervical mucosa, 1-2 mm in the greatest thickness. The endometrial cavity is 1.8 cm in height and 1.5 cm in width and is lined by flat, hemorrhagic endometrium 1-2 mm in greatest thickness with no discrete lesions. A 1.5 x 1 x 1 cm white, firm whorled solid nodule, well-encapsulated is attached to the lower uterine segment and extends into the parametrial tissue, grossly consistent with leiomyoma. Multiple sections of the myometrium show no evidence of additional tumors or invasive carcinoma. The ovaries and fallopian tubes are not oriented. Each ovary measures approximately 2 x 1 x 1 cm in size. Also each of them shows, on its surface, towards the lateral fold a 1.5 x 1 x 1 cm polypoid with papillary tan tumor which appears to be a superficial implant. Each fallopian tube is 5.5 cm in length and 0.5 to 1.0 cm in diameter. One of the fallopian tubes shows adhesions at its fimbriated end and is markedly distended, filled with clear fluid, consistent with hydrosalpinx. The other fallopian tube is distended by a 1.5 x 1.5 x 1.0 cm solid tumor that fills the lumen in the middle and proximal third. Labeled C1 - anterior cervix/endocervix; C2 - anterior endocervix/LUS; C3 - anterior endomyometrium; C4 - tumor implant on anterior uterine serosa; C5 - posterior cervix/endocervix; C6 - posterior endocervix/LUS; C7 - posterior endomyometrium; C8 and C9 - one ovary with corresponding fallopian tube; C10 - opposite ovary with its corresponding fallopian tube; C11-C15 - additional endomyometrium (entire endometrium submitted). Jar 2.

Source: NCI Genomic Data Commons file fe3dc916-0b58-4d76-bef0-349bae3167bc (TCGA-24-1463.864CB084-569A-47F0-A83D-F3FA649A6B00.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).